Somatic mutation profile of tumor specimen MP2PRT-PAVXMC-TMP1-A (aliquot MP2PRT-PAVXMC-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVXMC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,288 days).
Specimen MP2PRT-PAVXMC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 195a6745-e4e5-430c-8b95-b9624d600826.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXMC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXMC-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e56ef88-48bc-4d05-9407-1959f5c6525f

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, In Frame Ins 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 130/578 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BSN | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 136/569 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99608597; called by muse, mutect2, varscan2
- COQ8B | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 164/559 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV54577710; called by muse, mutect2, varscan2
- EXTL1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 106/424 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs146384192; called by muse, mutect2, varscan2
- FAM47A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 137/365 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs974876265, COSV100649779; called by muse, mutect2, varscan2
- FPR1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 124/465 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs765164623, COSV104395338; called by muse, mutect2, varscan2
- PCDHA4 | c.2141C>A p.T714K | Missense Mutation (SNP) | VAF 134/463 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as COSV63538900; called by muse, mutect2, varscan2
- SLC17A6 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs754093521; called by muse, mutect2, varscan2
- TRIM10 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 248/1013 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs760940395, COSV64989959; called by muse, mutect2, varscan2
- ADAM29 | c.1943G>T p.W648L | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DUOX1 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 107/412 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV2-70 | c.357_358insGAACCCGAGG | In Frame Ins (INS) | VAF 26/135 reads (19%) | called by mutect2, pindel, varscan2
- IGLV1-44 | chr22:22381346 ins CCT | In Frame Ins (INS) | VAF 87/340 reads (26%) | called by mutect2, pindel*, varscan2
- ESPL1 | c.1782G>A p.A594= | Silent (SNP) | VAF 121/525 reads (23%) | catalogued as rs147987096; called by muse, mutect2, varscan2
- TTN | c.54324C>T p.D18108= (on ENST00000591111; = p.D10684= on NM_003319.4) | Silent (SNP) | VAF 108/477 reads (23%) | catalogued as rs587780491; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- DCHS2 | n.3126A>G | RNA (SNP) | VAF 87/350 reads (25%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899618 TGTGGTAT>ACC | 3'Flank (DEL) | VAF 92/505 reads (18%) | called by pindel, varscan2*
